Surgical pathology report (de-identified scan), TCGA case TCGA-PC-A5DO, project TCGA-SARC (Sarcoma), tissue source site Fox Chase, specimen TCGA-PC-A5DO-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB:
Sex: F
Location:
Date Collected:
Date Received:
Physician:
Copy To:
Clinical History/Diagnosis: Retroperitoneal Sarcoma, Fibroid Uterus. Fatty Tumor of Left Buttock.

ICD-0-3
Leiomyosarcoma NOS
8890/3
Site Retroperitoneum
C48.0
JW 5/24/13

Source of Specimen(s):

- 1: Section of sigmoid colon, associated mesentery and mesenteric tumor
- 2: Fatty tumor of left buttock
- 3: Right tube and ovary
- 4: Left tube and ovary
- 5: Uterus

Gross Description:

Received in five parts.

Source of Tissue: 1. Labeled #1, "section of sigmoid colon with associated mesentery and mesenteric tumor"

Gross Description: Received fresh labeled "section of sigmoid colon with associated mesentery and mesenteric tumor" is a 9.0 cm in length fragment of bowel having a tan-pink serosa with a minimal amount of attached adipose tissue. There is a stitch present marking the proximal aspect. On opening the bowel averages 4.5 cm in circumference with the wall averaging 0.5 cm in thickness. The mucosa is tan, glistening with the usual folds. No mucosal lesions are grossly identified. Within the attached mesenteric fat there is a 6.0 x 4.5 x 4.0 cm mass having a tan to pink-red smooth outer surface. The circumferential margin is inked black. It is sectioned to reveal light-tan firm nodular cut surfaces. There are no palpable lymph nodes in the attached adipose tissue. Representative sections are submitted in ten blocks.

Designation of Sections: 1A- proximal bowel margin, 1B- distal bowel margin, 1C- random sections bowel, 1D-1H- mesenteric mass, 1I-1J- representative sections attached adipose tissue

Summary of Sections: multiple

Note: Tissue is Submitted for

Criteria	W 3/25/13	Yes	No

[page 2 of 4]
Source of Tissue: 2. Labeled #2, "fatty tumor of left buttock"

Gross Description: Received fresh labeled "fatty tumor of left buttock" is a 10.0 x 6.5 x 2.5 cm yellow-tan partially encapsulated fragment of adipose tissue. It is covered in part by a 5.5 x 1.5 cm light-tan skin ellipse. The margins are inked in black, it is sectioned to reveal yellow-tan glistening lobulated cut surfaces. Representative sections are submitted in six blocks.

Designation of Sections: 2A-2F

Summary of Sections: multiple

Source of Tissue: 3. Labeled #3, "right tube and ovary"

Gross Description: Received fresh labeled "right tube and ovary" is a 2.0 x 1.0 x 0.8 cm tan firm ovary. It is covered in part by a 3.5 x 0.5 cm gray-pink fragment of fallopian tube having a pin-point lumen and one fimbriated end. There are several clear fluid filled paratubal cysts, 0.4 cm in greatest dimension. The ovary is sectioned to reveal tan firm unremarkable cut surfaces. Representative sections are submitted in two blocks.

Designation of Sections: 3A-3B

Summary of Sections: multiple

Source of Tissue: 4. Labeled #4, "left tube and ovary"

Gross Description: Received fresh labeled "left tube and ovary" is a 1.5 x 1.0 x 0.8 cm tan firm ovary. It is covered in part by a 3.0 x 0.5 cm tan-pink fragment of fallopian tube having a pin-point lumen and one fimbriated end. The ovary is sectioned to reveal tan firm unremarkable cut surfaces. Representative sections are submitted in two blocks.

Designation of Sections: 4A-4B

Summary of Sections: multiple

Source of Tissue: 5. Labeled #5, "uterus"

Gross Description: Received fresh labeled "uterus" is a 60 gram uterus with attached cervix. The uterine body is 5.0 x 4.5 x 3.5 cm in greatest dimension being covered by a tan-pink serosa. The attached cervix is 4.0 x 3.5 x 3.5 cm having a red-purple hyperemic exocervix with a 0.4 cm patulous os. The specimen is bivalved to reveal a tan glistening endocervix with a minimal amount of mucus. The myometrium is tan, firm, 1.5 cm in greatest thickness. It contains a 1.5 cm in greatest dimension intramural leiomyoma having white-tan whorled bulging

[page 3 of 4]
cut surfaces. The uterine cavity is lined by a tan glistening endometrium, 0.3 cm in greatest thickness. Representative sections are submitted in six blocks.

Designation of Sections: 5A- anterior cervix, 5B- posterior cervix, 5C-5D- anterior endometrium/myometrium, 5E-5F- posterior endometrium/myometrium

Summary of Sections: multiple

Final Diagnosis:

1. Portion of sigmoid colon with associated mesentery and mesenteric tumor:

- Leiomyosarcoma of mesentery, 6.0 cm grossly, grade II.
- Lymphovascular invasion is not identified.
- Tumor is present at inked circumferential margin.
- Sigmoid colon and proximal and distal colonic resection margins, no tumor seen.
- One mesenteric lymph node, no tumor seen (0/1).

pT2bN0Mx

Note: Pleomorphic tumor cells are seen in some areas. Mitotic rate is up to 40 mitoses/10HPF focally. No necrosis is identified.

2. Left buttock tumor, excision:- Consistent with lipoma.

- Overlying skin with no significant pathological changes.

3. Right fallopian tube and ovary, salpingo-oophorectomy:

- Fallopian tube with paratubal cysts.
- Ovary with no significant pathological changes.

4. Left fallopian tube and ovary, salpingo-oophorectomy:- Ovary with a benign simple cyst.

- Fallopian tube with no significant pathological changes.

5. Uterus, total hysterectomy:- Inactive endometrium.

- Leiomyoma with hyalinization, 1.5 cm grossly.
- Endometrial stromal nodules, 3 mm and 2 mm microscopically.
- Cervix with squamous metaplasia.

Procedures/Addenda

Cytogenetics Solid Tumor Date Ordered:

Status:

Date Complete

By:

Date Reported

[page 4 of 4]
Results-Comments

CYTOGENETIC ANALYSIS REPORTS

TESTING CENTER:

DIAGNOSIS: Sarcoma

KARYOTYPE: Normal female karyotype:

RESULTS: The sarcoma sample was harvested after seventeen days in culture. The chromosomes from nineteen metaphases were counted and analyzed, and three of these metaphases were karyotyped by G-banding. The modal chromosome number was 46, and the cells appeared to have a normal karyotype. The normal results may reflect an overgrowth of normal interstitial tissue rather than tumor. A preliminary report was given to

Source: NCI Genomic Data Commons file 4d65d2f4-4042-4251-979a-909e36b7a5e4 (TCGA-PC-A5DO.F07CC3C0-230A-44F2-880E-182A6A8FBBD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).